CGCI case BLGSP-71-30-00645 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/61a13f32-83e7-4d9e-bfe9-9de6661c022e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 18 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: primary; Age at diagnosis: 61.9 years (22,591 days); Year of diagnosis: 2007; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 16 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Immunodeficiency-associated, adult; Max tumor bulk site: Inguinal; Sites of involvement: Bone marrow / Central nervous system.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Inguinal; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 4 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Methotrexate + Prednisone; Treatment intent type: Palliative; Days to treatment start: 6 days; Days to treatment end: 6 days; Number of cycles: 1; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 3.
- Days to follow up: 16 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day -359.

Molecular and laboratory tests
- CD10 (Flow Cytometry): Negative; Specialized molecular test: CD10 > 30%.
- CD23 (Flow Cytometry): Negative.
- CD5 (Flow Cytometry): Negative.
- MYC translocation (FISH): Abnormal, NOS.
- Test (Flow Cytometry): Positive; Specialized molecular test: FMC-7.
- Test (Flow Cytometry): Positive; Specialized molecular test: Surface Ig.
- Lactate Dehydrogenase 911 [Blood test normal range upper: 180].

Other clinical attributes
- Day -359: Comorbidities: HIV/AIDS.
- Day -359: Risk factors: HIV/AIDS.
- Day 0: CD4 count: 180; Haart treatment indicator: Yes; HIV viral load: 0.
- Day 16: Nadir CD4 count: 180.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00645-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00645-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00645-01-CD20: Tissue microarray coordinates: C2,D2.
  Slide BLGSP-71-30-00645-01-BCL2: Tissue microarray coordinates: C2,D2.
  Slide BLGSP-71-30-00645-01-CD3: Tissue microarray coordinates: C2,D2.
  Slide BLGSP-71-30-00645-01-CD10: Tissue microarray coordinates: C2,D2.
  Slide BLGSP-71-30-00645-01-Ki67: Tissue microarray coordinates: C2,D2.
  Slide BLGSP-71-30-00645-01-BCL6: Tissue microarray coordinates: C2,D2.
  Slide BLGSP-71-30-00645-01-EBER: Tissue microarray coordinates: C2,D2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV rna load at diagnosis: 0; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 3; Extranodal involvment other: CNS and possible renal infiltration; Lymph nodes examined: Yes; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 911; Immunophenotypic analysis method: Flow cytometry, not otherwise specified.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: FMC.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Treatments, Treatment 1: Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Cyclophosphamide, Prednisone; Pharma adjuvant cycles count: 1; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: intrathecal methotrexate and cytarabine; Pharma adjuvant cycles count: 1; Treatment best response: Clinical Progressive Disease.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00645-01A-01E-0001-01:
- % tumour: 90
